TCGA case TCGA-X6-A7WC — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: University of Iowa. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1c89da99-9e89-4726-b196-97eeab46d504

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 74 years; Vital status: Alive.

Diagnoses (5)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 74.6 years (27,252 days); Year of diagnosis: 2011; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 6.7; Tumor length measurement: 11.1; Tumor width measurement: 11.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 7.9; Tumor length measurement: 9.5; Tumor width measurement: 9.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Tumor burden: 11.1.
   Pathology details: Measurement type: Radiologic; Tumor burden: 9.5.
2. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 75.4 years (27,553 days); Days to diagnosis: 301 days; Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Tumor burden: 4.4.
   Pathology details: Measurement type: Radiologic; Tumor burden: 2.5.
3. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 76.2 years (27,846 days); Days to diagnosis: 594 days (1.6 years); Prior treatment: Yes; Tumor focality: Unifocal.
4. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 76.7 years (28,014 days); Days to diagnosis: 762 days (2.1 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Tumor burden: 3.4.
5. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 77.4 years (28,281 days); Days to diagnosis: 1,029 days (2.8 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 6.5; Tumor width measurement: 2.

Follow-up (8 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 1.
- Day 301 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 301 days; Discontiguous lesion count: 3.
- Day 594 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 594 days (1.6 years).
- Day 762 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 762 days (2.1 years).
- Days to follow up: 826 days (2.3 years); Disease response: With Tumor.
- Day 1,029 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 1,029 days (2.8 years).
- Days to follow up: 1,120 days (3.1 years); Disease response: Tumor Free.
- Days to follow up: 1,379 days (3.8 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-X6-A7WC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 100 mg.
  Slide TCGA-X6-A7WC-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-X6-A7WC-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-X6-A7WC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Negative; Tumor total necrosis: <10% (focal necrosis); Disease multifocal indicator: No; Discontinuous lesions count: 1; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Thigh/knee.
- Primary pathology, Tumor sizes, Tumor size: Lesion radiologic width: 9.0; Lesion pathologic width: 11.0.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 819; Days from index date to pharmaceutical treatment ended: 854; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Stable Disease.
- Drug treatment, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Radiation treatment 1: Days from index date to radiation therapy started: 69; Days from index date to radiation therapy ended: 125; Radiation therapy type: External; Radiation total dose: 7000; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 35; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No.
- Radiation treatment 2: Days from index date to radiation therapy started: 624; Days from index date to radiation therapy ended: 634; Radiation therapy type: External; Radiation total dose: 50; Radiation adjuvant units: Gy; Radiation adjuvant fractions total: 5; Radiation therapy site: Distant Recurrence; Radiation therapy ongoing indicator: No; Treatment best response: Stable Disease.
- Radiation treatment 3: Days from index date to radiation therapy started: 886; Days from index date to radiation therapy ended: 895; Radiation therapy type: External; Radiation total dose: 50; Radiation adjuvant units: Gy; Radiation adjuvant fractions total: 5; Radiation therapy site: Distant Recurrence; Radiation therapy ongoing indicator: No; Treatment best response: Radiographic Progressive Disease.
- Radiation treatment 4: Days from index date to radiation therapy started: 1042; Days from index date to radiation therapy ended: 1051; Radiation therapy type: External; Radiation total dose: 50; Radiation adjuvant units: Gy; Radiation adjuvant fractions total: 5; Radiation therapy site: Distant Recurrence; Radiation therapy ongoing indicator: No; Treatment best response: Partial Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,379 days; disease-specific survival: no event (censored), 1,379 days; disease-free interval: event (new tumor event after initially disease-free), 301 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 301 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-X6-A7WC-01A-12D-A350-01): tumor purity 0.66, ploidy 3.11, whole-genome doublings 1.
